Surgical pathology report (de-identified scan), TCGA case TCGA-GC-A3RB, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-GC-A3RB-01A (Primary Tumor).

[page 1 of 5]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

LAB:

Phone:

Fax:

Final Report

DIAGNOSIS

A) PROSTATE AND URINARY BLADDER, RADICAL CYSTOPROSTATECTOMY:

1. Invasive grade 3 (of 3) urothelial carcinoma, size 7 cm
2. See staging parameters for bladder cancer
3. Incidental foci (two) of prostatic adenocarcinoma (Gleason grade 3 + 3 = score 6) involving the right prostate, sizes 2 mm and 3 mm
4. See staging parameters for prostate cancer also

B) RIGHT DISTAL URETER, BIOPSY:

Negative for dysplasia or malignancy

C) LEFT DISTAL URETER, BIOPSY:

Negative for dysplasia or malignancy

D) RIGHT PELVIC LYMPH NODE, DISSECTION:

Five lymph nodes negative for malignancy

E) LEFT PELVIC LYMPH NODES, DISSECTION:

Four lymph nodes negative for malignancy

F) APPENDIX, INCIDENTAL APPENDECTOMY:

Appendix showing no diagnostic change

** BLADDER CANCER STAGING PARAMETERS**

Case number

Final TNM: pT3bN0M0

stage: III

MACROSCOPIC

SPECIMEN TYPE

Radical cystoprostatectomy

TUMOR SITE

Trigone, Right lateral wall, Anterior wall

TUMOR SIZE

Tumor maximum dimension: 7 cm

MICROSCOPIC

HISTOLOGIC TYPE

Urothelial (transitional cell) carcinoma

ASSOCIATED EPITHELIAL LESIONS

None identified

HISTOLOGICAL GRADE

High-grade (Grade 3 of 3 by prior WHO terminology)

LYMPHATIC VASCULAR INVASION

Indeterminate

ICD-O-3
carcinoma, urothelial, NOS

812013

Site: bladder, trigone

C67.0

3-30-12 RD

[page 2 of 5]
TUMOR CONFIGURATION

Solid/nodule

TUMOR EXTENSION

Perivesical fat

MARGINS

Uninvolved by carcinoma

Distance of invasive carcinoma to closest margin: 0.5 cm

Closest margin(s): Deep radial

Uninvolved by carcinoma in situ

PATHOLOGIC STAGING

EXTENT OF INVASION

pT3b. [Tumor invades perivesical tissue macroscopically
(extravesical mass)]

REGIONAL LYMPH NODES

pN0. (No lymph node metastasis)

Total nodes: 9

Total positive nodes: 0

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT3bN0M0

stage: III

** The pathologic stage presumes no distant metastasis.

PROSTATE CANCER STAGING PARAMETERS***

Final TNM: pT2aN0M0

stage: I

MACROSCOPIC

SPECIMEN TYPE

Pelvic lymph node dissection, cystoprostatectomy

PSA SCORE

Not available

MICROSCOPIC

HISTOLOGIC TYPE

Adenocarcinoma

HISTOLOGIC GRADE

Gleason grade: 3 + 3

Gleason score: 6 of 10 (primary + secondary)

MARGINS

Uninvolved by tumor

LYMPHATIC/VASCULAR INVASION

Absent

PERINEURAL INVASION

Not identified

PATHOLOGIC STAGING

EXTENT OF INVASION

pT2a. (Tumor confined within prostate, involves one half of one
lobe or less)

Maximal dimension is difficult to determine; see tumor percent.

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

Total nodes: 9

Total positive nodes: 0

DISTANT METASTASIS

pM0. (No distant metastasis)

[page 3 of 5]
[REDACTED]

PATHOLOGIC STAGE Summary

Final TNM: pT2aN0M0

2010 stage: I

** The pathologic stage presumes no distant metastasis.

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

Bladder cancer

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Bladder and prostate

The specimen is received fresh labeled "bladder and prostate." It consists of an 8 x 7.5 x 5 cm bladder. There is 3 cm of attached right ureter. The ureter appears dilated with a diameter of 0.6 cm. It is obstructed. The ureteral margin (not a true margin) is sectioned and submitted en face. There is 6 cm of attached left ureter. This ureter is patent and measures 0.4 cm in diameter. The ureteral (not a true margin) is sectioned and submitted en face. The attached prostate measures 4 (r-l) x 2.9 (anterior-posterior) x 2.6 (apex-base) cm. The right seminal vesicle measures 2 x 1.5 x 1 cm. The left seminal vesicle measures 2 x 1 x 0.7 cm. The right vas deferens measures 8 cm in length and up to 0.4 cm in diameter. The left vas deferens measures 5 cm in length and up to 0.2 cm in diameter. The right half of the specimen is inked green, the left half inked blue and the posterior aspect inked black.

The distal urethral margin is sectioned in a radial fashion and entirely submitted for frozen labeled FS1 and FS2.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Urethral margin negative" is rendered by [REDACTED]

The specimen is opened along the anterior aspect. There is a 7 x 4.1 x 1 cm partially endophytic, partially exophytic mass. The mass is found within the trigone and extends up to a portion of the posterior wall, right lateral wall and right aspect of the anterior wall. It extends to within 1.5 cm of the distal urethral margins. It appears to obstruct the right ureteral orifice. It is found 1.3 cm from the left ureteral orifice. A representative section of the tumor is sectioned and frozen for possible ancillary studies. It is sectioned. It extends into the bladder wall for a maximum depth of 2.1 cm. The bladder wall measures 2.2 cm and the tumor extends to within 0.1 cm of the right lateral soft tissue margin. The cut surface is tan and firm.

The remaining urothelium is moderately hyperemic and coarsely wrinkled. No additional lesions are noted.

The prostate is serially sectioned. The cut surfaces are mottled tan-pink. No obvious tumor is appreciated. The seminal vesicles are sectioned and are grossly unremarkable. The vasa deferentia are sectioned revealing pinpoint unremarkable lumina.

A gross photo is taken.

There are no palpable lymph nodes in the attached fat.

Representative sections are submitted in 29 cassettes labeled:

1-2. Frozen section residue, distal urethral margin, sectioned in a radial fashion

[REDACTED]

[page 4 of 5]
- [REDACTED]
3. Right and left ureteral margins (not true margins), en face
4. Obstructed right ureteral orifice
5. Tumor and posterior walls
- 6-7. Tumor's greatest depth and nearest soft tissue margin
8. Tumor at trigone
9. Tumor anterior wall
10. Left ureteral orifice
11. Uninvolved left urothelium
12. Uninvolved anterior urothelium
13. Uninvolved posterior urothelium
- 14-17. Right prostate, apex to base (cassette 17 includes longitudinal section, seminal vesicle)
- 18-22. Left prostate, apex to base (cassette 22 includes longitudinal sections, seminal vesicle)
23. Vasa deferentia margins, en face

The remainder of the apparent prostate is submitted as follows:

- 24-25. Portion of right prostate
26. Portion of possible right prostate and bladder tumor
27. Portion of possible right prostate and bladder tumor
28. Portion of left prostate
29. Portion of possible left prostate (includes portion of bladder and tumor)
- [REDACTED]

B) SOURCE: Distal right ureter

Labeled "right distal ureter" is a 0.6 cm in length cylindrical portion of tissue measuring 0.8 cm in diameter. It is submitted as received in one chunk for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Negative" is rendered by [REDACTED]

C) SOURCE: Left distal ureter

Labeled "left distal ureter" is a tan-pink cylindrical 0.6 cm in length x 0.6 cm in diameter portion of tissue. It is entirely submitted on for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Negative" is rendered by [REDACTED]

[REDACTED]

D) SOURCE: Lymph nodes, right pelvic

Labeled "right pelvic lymph nodes" are several yellow-tan ragged fatty tissues aggregating 5 x 4 x 1 cm. Five lymph nodes are identified ranging from 0.4-2.8 cm in greatest dimension. The nodes are submitted in four cassettes as follows:

1. Three nodes
2. One node
- 3,4. One node

E) SOURCE: Lymph nodes, left pelvic

Labeled "left pelvic lymph nodes" is a 3 x 2 x 2 cm portion of yellow-tan ragged fatty tissue. Four lymph nodes are identified ranging from 0.9-3.5 cm in greatest dimension. The nodes are submitted in five cassettes as follows:

1. One node
- 2-3. One node
4. One node
- [REDACTED]

[page 5 of 5]
5. One node

F) SOURCE: Appendix

Labeled "appendix" is an intact vermiform appendix measuring 2.8 cm in length averaging 0.5 cm in diameter with attached mesoappendiceal fat measuring 2 x 0.5 cm. The serosal surface is pink-tan and smooth with an unremarkable lumen without masses, perforations or fecaliths identified. Representative sections to include the proximal margin (inked) are submitted in a single cassette.

This case is accessioned in

Gross dictation by:

MICROSCOPIC

A-F) The microscopic appearance substantiates the diagnosis. Dictation by:
transcribed by

Interpreted at

COLLECTED: ACCESSIONED: SIGNED:

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL
Information

Lab and Collection

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL
Report

Order Result History

Lab Status

Order Complete [3]

on

Result Information

Result Date and Time

Status

Final result

Provider Status

Ordered

Lab Information

Order Details

Parent Order ID

Child Order ID

Entry Date

Specimen Information

Specimen Source

Collection Date

Collection Time

Other

Audit Trail

Source: NCI Genomic Data Commons file c4a6bc84-8c15-4efb-9acb-30078b103113 (TCGA-GC-A3RB.2783B3D4-83FA-4E66-A424-715CAC7EFD53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).